Surgical pathology report (de-identified scan), TCGA case TCGA-20-0996, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site Fox Chase Cancer Center, specimen TCGA-20-0996-01A (Primary Tumor).

[page 1 of 6]
Age:
Sex: F
Clinical History/Diagnosis: Not entered.

Source of Specimen(s):

- A: CYTOLOGY
- B: OMENTUM
- C: ADDITIONAL SUPRACOLIC OMENTUM
- D: RT TUBE OVARY
- E: ADDITIONAL TUMOR FROM GREATER CURVATURE OF ST
- F: BLADDER PERITONEUM TUMOR
- G: UTERUS,LT TUBE OVARY RECTUM
- H: TUMOR @ SPLENIC FLEXURE
- I: EEA HEAD WITH DISTAL PORTION
- J: TUMOR FROM LT COLON
- K: RT PARACOLIC NODULE

Clinical History/Diagnosis: PELVIC MASS; (+) BX FOR ADENOCA

Specimen(s): 1 CYTOLOGY

- 2 OMENTUM
- 3 ADDITIONAL SUPRACOLIC OMENTUM
- 4 R TUBE AND OVARY
- 5 ADDITIONAL TUMOR FROM GREATER CURVATURE OF STOMACH
- 6 BLADDER PERITONEUM TUMOR
- 7 UTERUS, L TUBE AND OVARY, AND RECTUM
- 8 TUMOR AT SPLENIC FLEXURE
- 9 EEA HEAD WITH DISTAL PORTION
- 10 TUMOR FROM L COLON
- 11 R PARACOLIC NODULE

*

Gross Description:

GROSS DESCRIPTION: Received in eleven parts.

SOURCE OF TISSUE: 1. CYTOLOGY.

*

SOURCE OF TISSUE: 2. Labeled #2, "omentum"

FROZEN SECTION DIAGNOSIS: 2FS - PAPILLARY SEROUS CARCINOMA

GROSS DESCRIPTION: Received fresh for frozen section evaluation is a 32.0

[page 2 of 6]
X 15.0 x 6.5 cm portion of caked omental fat. It is sectioned to reveal multiple clear fluid-filled cysts, 1.0 to 3.5 cm in greatest dimension. The remaining cut surfaces are tan, firm and sponge-like. Two representative sections are submitted for frozen section evaluation and the frozen section residue is submitted in one block. Additional representative sections are submitted in four blocks.

DESIGNATION OF SECTIONS: 2FS, 2A-2D

SUMMARY OF SECTIONS: FS, A-D - multiple

*

SOURCE OF TISSUE: 3. Labeled #3, "additional supracolic omentum"

GROSS DESCRIPTION: Received fresh are 11.0 x 5.0 x 3.5 cm of caked Omental fragments. They are sectioned to reveal multiple clear fluid-filled cysts, 1.5 cm in greatest dimension. The remaining cut surfaces are tan, soft and sponge-like. Representative sections are submitted in three blocks.

DESIGNATION OF SECTIONS: 3A-3C

SUMMARY OF SECTIONS: each block has one piece

*

SOURCE OF TISSUE: 4. Labeled #4, "right tube and ovary"

GROSS DESCRIPTION: Received fresh are two tan to red-purple irregular Soft tissue fragments, 4.0 x 2.5 x 2.0 cm and 4.5 x 4.0 x 2.0 cm in greatest dimension. They are sectioned to reveal tan soft to friable cut surfaces. The fallopian tube is not readily identified. Representative sections are submitted in four blocks.

DESIGNATION OF SECTIONS: 4A - ? fallopian tube, 4B-4D - representative sections, tissue fragments

SUMMARY OF SECTIONS: A-D - multiple

*

SOURCE OF TISSUE: 5. Labeled #5, "additional tumor from greater Curvature of stomach"

GROSS DESCRIPTION: Received fresh is a 7.5 x 2.5 x 2.0 cm yellow-tan fragment of omental fat. It is sectioned to reveal tan glistening cut

[page 3 of 6]
surfaces containing multiple tan-pink tumor nodules, 1.5 cm in greatest dimension. Representative sections are submitted in two blocks.

DESIGNATION OF SECTIONS: 5A-5B

SUMMARY OF SECTIONS: A-B - multiple

*

SOURCE OF TISSUE: 6. Labeled #6, "bladder peritoneum tumor"

GROSS DESCRIPTION: Received fresh is a 5.0 x 2.0 x .5 cm tan fragment of tumor which is sectioned to reveal soft firm to friable cut surfaces. Representative sections are submitted in two blocks.

DESIGNATION OF SECTIONS: 6A-6B

SUMMARY OF SECTIONS: A-2,B-2

*

SOURCE OF TISSUE: 7. Labeled #7, "uterus, left tube and ovary and rectum"

GROSS DESCRIPTION: Received fresh is a 28.0 cm in length fragment of large bowel and rectum having a tan-pink serosa with an abundant amount of attached adipose tissue. The bowel is adhered upon itself and on sectioning through the attached adipose tissue there are multiple tan tumor nodules, 3.0 cm in greatest dimension. 5.0 cm from the proximal margin of resection there is an attached uterus with cervix and left adnexa. The uterine body

is 3.5 x 3.0 x 2.5 cm in greatest dimension having a tan-pink shaggy serosa.

The attached cervix is 3.0 x 2.5 x 2.0 cm in greatest dimension having a tan-pink exocervix with a 0.3 cm patulous os. The specimen is bivalved to

reveal a tan glistening endocervix with a minimal amount of mucus. The myometrium is tan-pink, 1.0 cm in greatest thickness. The uterine cavity is lined by a tan glistening endometrium, 0.3 cm in greatest thickness. The attached left ovary is approximately 3.5 x 2.5 x 2.0 cm in greatest dimension, which is sectioned to reveal tan, friable tumor. It is covered

in part by a 3.5 x 0.6 cm tan-pink fallopian tube having a pin point lumen

[page 4 of 6]
and one fimbriated end. The ovary/tumor is firmly adherent to the large bowel. On opening the bowel ranges from 3.0 to 5.5 cm in greatest circumference with the wall averaging 0.5 cm in thickness. The mucosa is tan, glistening, slightly edematous, with the usual folds. In the mid portion of the bowel there is a 1.0 cm in greatest dimension tan pedunculated polyp. No additional mucosal lesions are grossly identified.

Representative sections are submitted in fifteen blocks.

DESIGNATION OF SECTIONS: 7A - proximal margin, 7B - distal margin, 7C-7D - random sections bowel, 7E - pedunculated polyp, 7F - random sections tumor

nodules in attached adipose tissue, 7G - anterior cervix, 7H - posterior cervix, 7I-7J - anterior endometrium/myometrium, 7K-7L - posterior endometrium/myometrium, 7M - fallopian tube, 7N-7O - area of ovary/tumor with attached bowel wall

SUMMARY OF SECTIONS: A-O - multiple

*

SOURCE OF TISSUE: 8. Labeled #8, "tumor at splenic flexure"

GROSS DESCRIPTION: Received fresh is an 11.5 x 8.0 x 3.5 cm tan to pink-red firm fragment of tissue. It is sectioned to reveal multiple clear fluid filled cysts, 2.0 cm in greatest dimension. The remaining cut surfaces are light tan and sponge like. Representative sections are submitted in three blocks.

DESIGNATION OF SECTIONS: 8A-8C

SUMMARY OF SECTIONS: each block has one piece

*

SOURCE OF TISSUE: 9. Labeled #9, "EEA head with distal portion"

GROSS DESCRIPTION: Received fresh on a stapler spike are two tan-pink annular fragments of mucosa, 2.0 cm in greatest dimension. The fragments are not specifically designated. Each contains multiple staples, these

[page 5 of 6]
removed, and the remaining soft tissue is entirely submitted in four blocks.

DESIGNATION OF SECTIONS: 9A-9B - rounded end, 9C-9D - pointed end

SUMMARY OF SECTIONS: A-D - multiple

SOURCE OF TISSUE: 10. Labeled #10, "tumor from left colon"

GROSS DESCRIPTION: Received fresh is a 6.0 x 3.5 x 2.0 cm tan to pink-red fragment of soft tissue. It is sectioned to reveal cut surfaces infiltrated by tan tumor. There are multiple clear fluid-filled cysts, 1.0 cm in greatest dimension. Representative sections are submitted in two blocks.

DESIGNATION OF SECTIONS: 10A-10B

SUMMARY OF SECTIONS: A-1,B-1

SOURCE OF TISSUE: 11. Labeled #11, "right paracolic nodule"

GROSS DESCRIPTION: Received fresh is a 9.5 x 5.0 x 2.5 cm yellow-tan fragment of fibroadipose tissue. It is sectioned to reveal cut surfaces which are infiltrated by tan tumor. Also present are several clear fluid-filled cysts, 1.0 cm in greatest dimension. Representative sections are submitted in two blocks.

DESIGNATION OF SECTIONS: 11A-11B

SUMMARY OF SECTIONS: A-B - multiple

Final Diagnosis:

DIAGNOSIS:

1. CYTOLOGY.

2. OMENTUM, OMENTECTOMY:

- METASTATIC SEROUS PAPILLARY CARCINOMA.

3. OMENTUM, SUPRACOLIC, ADDITIONAL, EXCISION:

[page 6 of 6]
- METASTATIC SEROUS PAPILLARY CARCINOMA.

4. RIGHT OVARY AND FALLOPIAN TUBE, SALPINGO-OOPHORECTOMY:
- SEROUS PAPILLARY CARCINOMA WITH SUPERFICIAL INVASION OF OVARY.

5. STOMACH, GREATER CURVATURE, EXCISION:
- METASTATIC SEROUS PAPILLARY CARCINOMA.

6. BLADDER PERITONEUM, EXCISION:
- METASTATIC SEROUS PAPILLARY CARCINOMA.
- TWO SMALL LYMPH NODES BOTH NEGATIVE FOR TUMOR (0/2).

7. UTERUS, LEFT OVARY AND FALLOPIAN TUBE AND RECTUM, RESECTION:
- SEROUS PAPILLARY CARCINOMA, INTERMEDIATE GRADE EFFACING THE LEFT OVARY AND INVADING THE LEFT FALLOPIAN TUBE.
- TUMOR INVADES OUTER RECTAL WALL AND UTERINE AND CERVICAL SEROSA WITH SUPERFICIAL INVASION.
- UTERUS WITH BENIGN ATROPHIC ENDOMETRIUM AND BENIGN ECTO AND ENDOCERVIX.
- TUBULAR ADENOMA OF RECTUM.
- PROXIMAL AND DISTAL MARGINS OF THE BOWEL NEGATIVE.

8. TUMOR AT SPLENIC FLEXURE, EXCISION:
- METASTATIC SEROUS PAPILLARY CARCINOMA.

9. EEA HEAD WITH DISTAL PORTION:
- NO TUMOR SEEN.

10. LEFT COLON, TUMOR, EXCISION:
- METASTATIC SEROUS PAPILLARY CARCINOMA.

11. RIGHT PARACOLIC NODULE, EXCISION:
- METASTATIC SEROUS PAPILLARY CARCINOMA.

Source: NCI Genomic Data Commons file 5218f31a-8e1a-40ef-a24c-822453b58671 (TCGA-20-0996.B9EF21BB-4075-4A29-8023-1874FD090BA5.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).